Somatic mutation profile of tumor specimen TCGA-GC-A3RC-01A (aliquot TCGA-GC-A3RC-01A-11D-A22Z-08) from TCGA case TCGA-GC-A3RC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 59.3 years (21,668 days).
Specimen TCGA-GC-A3RC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a142613-437f-41d8-9426-230e845800aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GC-A3RC-10B (Blood Derived Normal), aliquot TCGA-GC-A3RC-10B-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a49785a4-c849-4eb2-b020-bfe122870bc6

The open-access MAF lists 427 somatic variants for this specimen: 289 protein-altering or splice-affecting, 126 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 235, Silent 126, Nonsense Mutation 16, Splice Site 12, Frame Shift Del 10, In Frame Del 8, Splice Region 3, Intron 3, RNA 3, Frame Shift Ins 3, 5'Flank 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC2 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55538701; called by muse, mutect2, varscan2
- KDM6A | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 31/44 reads (70%) | hotspot (GDC flag); catalogued as COSV65037942; called by muse, mutect2, varscan2
- WNT7A | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397514666, CM110768, COSV53196797; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABL1 | c.601C>T p.H201Y | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); catalogued as COSV59325017; called by muse, mutect2, varscan2
- ACAP3 | c.525C>T p.I175= | Splice Region (SNP) | VAF 13/29 reads (45%) | catalogued as COSV61221432; called by muse, mutect2, varscan2
- ACO2 | c.934C>G p.R312G | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53441000; called by muse, mutect2, varscan2
- ADAM11 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775938319, COSV52344380; called by muse, mutect2, varscan2
- ADAM33 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs368581221; called by muse, mutect2, varscan2
- ADAMTSL3 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs139499552, COSV54436264; called by muse, mutect2, varscan2
- ADCY2 | c.1305G>C p.L435F | Missense Mutation (SNP) | VAF 94/153 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57859024; called by muse, mutect2, varscan2
- ADCY8 | c.2075C>T p.S692L | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as rs1042926370, COSV53896436; called by muse, mutect2, varscan2
- ADGRF4 | c.1628A>G p.Y543C | Missense Mutation (SNP) | VAF 151/238 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51949537; called by muse, mutect2, varscan2
- ADM | c.249-11_258del p.X83_splice | Splice Site (DEL) | VAF 16/44 reads (36%) | catalogued as COSV53402689; called by mutect2, pindel
- AFG3L2 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52312727; called by muse, mutect2, varscan2
- AFTPH | c.1343T>C p.F448S | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as COSV53215839; called by muse, mutect2, varscan2
- AHNAK | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV57216501; called by muse, mutect2, varscan2
- AKAP9 | c.8429T>G p.L2810R (on ENST00000359028; = p.L2786R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.315); catalogued as COSV62338692; called by muse, mutect2, varscan2
- ALDH1A1 | c.818A>C p.K273T | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52789182, COSV52789353; called by muse, mutect2, varscan2
- ANAPC4 | c.341A>G p.H114R | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV59542937; called by muse, mutect2, varscan2
- ANKRD17 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV58215467; called by muse, mutect2, varscan2
- ANKS1B | c.71C>A p.S24Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61335114; called by muse, mutect2
- ANOS1 | c.1004T>C p.M335T | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52916000; called by muse, mutect2, varscan2
- ARHGAP5 | c.2878C>G p.Q960E | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV61533923; called by muse, mutect2, varscan2
- ARID1A | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 19/91 reads (21%) | catalogued as COSV61373914; called by muse, mutect2, varscan2
- ARID3B | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV60556387, COSV60558258; called by muse, mutect2, varscan2
- ASCC3 | c.5478T>A p.H1826Q | Missense Mutation (SNP) | VAF 95/132 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64972235; called by muse, mutect2, varscan2
- ASPM | c.5976C>G p.I1992M | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1438607466, COSV54124645; called by muse, mutect2, varscan2
- B3GALT4 | c.1118T>A p.I373K | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV65851262; called by muse, mutect2, varscan2
- BCAS1 | c.577T>A p.F193I | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65083809, COSV65086046; called by muse, mutect2, varscan2
- BDP1 | c.5072G>A p.R1691K | Missense Mutation (SNP) | VAF 84/152 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as COSV62428925; called by muse, mutect2, varscan2
- BEND3 | c.1567G>A p.G523S | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated (0.25); PolyPhen benign (0.234); catalogued as COSV64679971; called by muse, mutect2, varscan2
- BNIP5 | c.1759G>C p.A587P | Missense Mutation (SNP) | VAF 76/101 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV71325281; called by muse, mutect2, varscan2
- BRPF1 | c.2617+2T>C p.X873_splice | Splice Site (SNP) | VAF 16/36 reads (44%) | catalogued as COSV57403178; called by muse, varscan2
- BTBD10 | c.1211C>A p.S404Y | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53397549; called by muse, mutect2, varscan2
- C1QL4 | c.568G>C p.D190H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57743067; called by muse, varscan2
- C5AR2 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.453); catalogued as rs767179541, COSV57255459; called by muse, mutect2, varscan2
- C9orf85 | c.64T>A p.F22I | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV58253459; called by muse, mutect2, varscan2
- CAPN6 | c.1820A>G p.D607G | Missense Mutation (SNP) | VAF 57/66 reads (86%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV60693845; called by muse, mutect2, varscan2
- CASR | c.2965G>C p.G989R (on ENST00000490131; = p.G1066R on NM_000388.4) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV56134217; called by muse, mutect2, varscan2
- CCDC33 | c.2187_2191del p.E729Dfs*8 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | catalogued as COSV51430620; called by mutect2, pindel, varscan2
- CCDC66 | c.427G>A p.E143K (on ENST00000394672 / NM_001353147.1; = p.E109K on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV58301384; called by muse, mutect2, varscan2
- CD2AP | c.320-1G>A p.X107_splice | Splice Site (SNP) | VAF 17/106 reads (16%) | catalogued as COSV63759241; called by muse, mutect2, varscan2
- CDCA4 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV60314976, COSV60316510; called by muse, mutect2
- CDH23 | c.9957G>C p.E3319D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.011); catalogued as COSV56447936; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5411C>T p.S1804L | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV62572091; called by muse, mutect2, varscan2
- CENPJ | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV67882916; called by muse, mutect2, varscan2
- CEP170B | c.4313T>C p.L1438P (on ENST00000453495; = p.L1367P on NM_015005.3) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV52043862; called by muse, mutect2, varscan2
- CHD6 | c.6659C>G p.S2220C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV64688397, COSV64694479; called by muse, mutect2, varscan2
- CHD7 | c.4111T>G p.L1371V | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV71107199; called by muse, mutect2, varscan2
- CHMP1B | c.495C>G p.N165K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV52323238; called by muse, mutect2, varscan2
- CNGB1 | c.2246A>G p.D749G | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51897639; called by muse, mutect2
- CNOT3 | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV55360043; called by muse, mutect2, varscan2
- COG5 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51742803; called by muse, mutect2, varscan2
- CORO6 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV61470111; called by muse, mutect2, varscan2
- CR2 | c.1247T>C p.I416T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65506038; called by muse, mutect2, varscan2
- CREBBP | c.3540G>C p.K1180N | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52114234; called by muse, mutect2, varscan2
- CRELD1 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV55972232; called by muse, mutect2, varscan2
- CRPPA | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as rs370499190, CM123226; called by muse, mutect2, varscan2
- CST8 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as rs375998352, COSV99850084; called by muse, mutect2, varscan2
- CYC1 | c.929A>G p.K310R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV59643674; called by muse, mutect2, varscan2
- CYP2A7 | c.1027T>C p.F343L | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.336); catalogued as COSV52497125; called by muse, mutect2, varscan2
- CYP2C9 | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV53246446, COSV99582229; called by muse, mutect2, varscan2
- CYP4F3 | c.352_356del p.V118Kfs*23 | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | catalogued as COSV55407123; called by mutect2, pindel, varscan2
- DCAF15 | c.228A>C p.A76= | Splice Region (SNP) | VAF 10/49 reads (20%) | catalogued as COSV54335092, COSV54337598; called by muse, mutect2, varscan2
- DCP1A | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV53687093; called by muse, mutect2, varscan2
- DDX24 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV58211807; called by muse, mutect2, varscan2
- DDX43 | c.130A>G p.S44G | Missense Mutation (SNP) | VAF 70/95 reads (74%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV64836405; called by muse, mutect2, varscan2
- DIP2B | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.831); catalogued as rs765204962, COSV56578863; called by muse, mutect2, varscan2
- DIS3L | c.265C>G p.Q89E (on ENST00000319212 / NM_001143688.3; = p.Q6E on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV59911003, COSV59912617; called by muse, mutect2, varscan2
- DLG4 | c.2166G>C p.E722D (on ENST00000399506 / NM_001321075.3; = p.E765D on NM_001365.4) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV57236557; called by muse, mutect2, varscan2
- DMD | c.5070C>A p.H1690Q | Missense Mutation (SNP) | VAF 52/64 reads (81%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV63735196; called by muse, mutect2, varscan2
- DMXL1 | c.1069_1101del p.F357_T367del | In Frame Del (DEL) | VAF 31/101 reads (31%) | catalogued as COSV60704884; called by mutect2, pindel
- DNAH5 | c.5437_5445del p.E1813_G1815del | In Frame Del (DEL) | VAF 25/97 reads (26%) | catalogued as COSV54204102; called by mutect2, pindel, varscan2
- DNAI3 | c.2289C>G p.I763M | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54000586; called by muse, mutect2, varscan2
- DNTTIP1 | c.493A>G p.K165E | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65459470; called by muse, mutect2, varscan2
- DOCK7 | c.6172C>G p.H2058D (on ENST00000635253 / NM_001367561.1; = p.H2027D on NM_033407.3) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV51995816; called by muse, mutect2, varscan2
- DPP8 | c.778G>C p.E260Q (on ENST00000341861 / NM_001320875.2; = p.E244Q on NM_017743.6) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.027); catalogued as COSV55675979; called by muse, mutect2, varscan2
- DRD3 | c.1188G>C p.K396N | Missense Mutation (SNP) | VAF 98/284 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55678607; called by muse, mutect2, varscan2
- DYRK4 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs774187466, COSV50537774; called by muse, mutect2, varscan2
- EIF2S3 | c.787G>C p.D263H | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53405806, COSV53406987; called by muse, mutect2, varscan2
- ELF3 | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62837193; called by muse, mutect2, varscan2
- ELL3 | c.570-1G>A p.X190_splice | Splice Site (SNP) | VAF 16/35 reads (46%) | catalogued as COSV55854716; called by muse, mutect2, varscan2
- EML1 | c.1708T>C p.W570R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51741500; called by muse, mutect2, varscan2
- EPB41L4A | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.862); catalogued as COSV54862706; called by muse, mutect2, varscan2
- EXO1 | c.2450T>G p.V817G | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV62216317; called by muse, mutect2, varscan2
- FAM120C | c.2189A>T p.K730I | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60257477; called by muse, mutect2, varscan2
- FAM181B | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV61300360, COSV61300480; called by muse, mutect2, varscan2
- FANCD2 | c.2054G>C p.G685A | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as COSV55032783, COSV55037198; called by muse, mutect2, varscan2
- FANCD2 | c.2238C>A p.N746K | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.209); catalogued as COSV55032797; called by muse, mutect2, varscan2
- FGFR1 | c.995C>T p.S332F (on ENST00000447712 / NM_023110.3; = p.S330F on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as CM070126, COSV58327622; called by muse, mutect2, varscan2
- FGR | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV64969207; called by muse, mutect2, varscan2
- FNDC1 | c.4044C>G p.I1348M | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51930848; called by muse, mutect2, varscan2
- FSIP1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.964); catalogued as COSV63223390; called by muse, mutect2, varscan2
- GBF1 | c.1549G>A p.E517K (on ENST00000369983 / NM_001377137.1; = p.E516K on NM_004193.3) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64142792; called by muse, mutect2, varscan2
- GKAP1 | c.563A>G p.D188G | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.547); catalogued as COSV64488558; called by muse, mutect2, varscan2
- GOLGA5 | c.727C>G p.Q243E | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV50832006; called by muse, mutect2, varscan2
- GPC5 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV65577261; called by muse, mutect2, varscan2
- GPRASP1 | c.3013T>C p.W1005R | Missense Mutation (SNP) | VAF 91/112 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64354780; called by muse, mutect2, varscan2
- GRIN2A | c.1898T>C p.V633A | Missense Mutation (SNP) | VAF 47/66 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV58020209; called by muse, mutect2, varscan2
- GRIP1 | c.366G>C p.K122N | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54015421; called by muse, mutect2
- GXYLT2 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1397029344, COSV67473398; called by muse, mutect2, varscan2
- GYS1 | c.19T>G p.L7V | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.16); catalogued as COSV54401305; called by muse, mutect2, varscan2
- H4C4 | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 86/126 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.538); catalogued as rs749934539, COSV61590686, COSV61591118; called by muse, mutect2, varscan2
- HAMP | c.10_21del p.S4_I7del | In Frame Del (DEL) | VAF 45/172 reads (26%) | catalogued as COSV55885237; called by mutect2, pindel, varscan2
- HMCN1 | c.9578-1G>C p.X3193_splice | Splice Site (SNP) | VAF 10/25 reads (40%) | catalogued as rs1326876772, COSV54877150; called by mutect2, varscan2
- HMGN1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as rs1374414294, COSV55742089; called by muse, mutect2, varscan2
- HTT | c.4711G>T p.V1571L | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.183); catalogued as COSV61857393; called by muse, mutect2, varscan2
- ICA1 | c.653T>A p.L218H | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55576058; called by muse, mutect2, varscan2
- IDE | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56421484; called by muse, mutect2, varscan2
- IFIT2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs1258918725, COSV51077865, COSV51078817; called by muse, mutect2, varscan2
- IFT81 | c.1747G>C p.D583H | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV54360513; called by muse, mutect2, varscan2
- INSM2 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV51876567; called by muse, mutect2, varscan2
- ITPR1 | c.3712G>A p.A1238T (on ENST00000354582; = p.A1223T on NM_002222.7) | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.996); catalogued as COSV56968292; called by muse, mutect2, varscan2
- IVNS1ABP | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV62250710; called by muse, mutect2, varscan2
- KDM3B | c.3202A>G p.T1068A | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV58687967; called by muse, mutect2, varscan2
- KIF18B | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV59270762; called by muse, mutect2, varscan2
- KLHL15 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 113/141 reads (80%) | SIFT tolerated (0.5); PolyPhen benign (0.025); catalogued as COSV60139130, COSV60142280; called by muse, mutect2, varscan2
- KLHL28 | c.725A>G p.H242R | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as COSV61887364; called by muse, mutect2, varscan2
- KMT2A | c.8021C>G p.S2674* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as COSV100628372; called by muse, mutect2, varscan2
- LAMA1 | c.3202A>G p.K1068E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67532112, COSV67538011; called by muse, mutect2, varscan2
- LRP2 | c.484C>G p.Q162E | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV55540920; called by muse, mutect2, varscan2
- LRRC42 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100066799, COSV59960099; called by muse, mutect2, varscan2
- LRRC47 | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65561961; called by muse, mutect2, varscan2
- LRRK2 | c.2718G>C p.K906N | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as COSV54143953; called by muse, mutect2, varscan2
- LYPD6B | c.7T>C p.Y3H (on ENST00000409029 / NM_001317004.1; = p.Y27H on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV54517723; called by muse, mutect2, varscan2
- LZTR1 | c.2264G>T p.R755L | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53145154; called by muse, mutect2, varscan2
- MAGIX | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs1185625654, COSV100891877, COSV66255692; called by muse, mutect2, varscan2
- MALT1 | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61934039; called by muse, mutect2, varscan2
- MAP1LC3A | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 86/275 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV54160391, COSV54162631, COSV54164858; called by muse, mutect2, varscan2
- MARK1 | c.1673C>G p.S558C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV65065543; called by muse, mutect2, varscan2
- MDC1 | c.3127C>T p.P1043S | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs1252888669, COSV64523231; called by muse, mutect2, varscan2
- MGA | c.2873C>G p.T958S | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs572851867, COSV54948847; called by muse, mutect2, varscan2
- MIDN | c.1327G>A p.G443S | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.168); catalogued as rs771481143, COSV56294049; called by muse, mutect2, varscan2
- MORC3 | c.1718A>G p.D573G | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV68687734; called by muse, mutect2
- MPDZ | c.5903C>G p.T1968S (on ENST00000319217 / NM_001330637.2; = p.T1939S on NM_003829.5) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs928785785, COSV59915515; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3370G>C p.E1124Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56616746, COSV56619256; called by muse, mutect2, varscan2
- MPP5 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs1249001844, COSV55527852; called by muse, mutect2, varscan2
- MRI1 | c.950-2A>G p.X317_splice (on ENST00000040663 / NM_001031727.4; = p.X270_splice on NM_032285.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 35/66 reads (53%) | catalogued as rs112124892; called by muse, mutect2, varscan2
- MS4A6E | c.335G>A p.R112K | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs759976527, COSV55726190; called by muse, mutect2, varscan2
- MTMR3 | c.505G>C p.G169R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV60301796; called by muse, mutect2, varscan2
- MTMR4 | c.1082G>A p.S361N | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as COSV60199332; called by muse, mutect2, varscan2
- MUC4 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 106/194 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); catalogued as COSV62129608; called by muse, mutect2, varscan2
- MYH9 | c.109G>C p.D37H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV53381956, COSV53382287; called by muse, mutect2, varscan2
- MYO16 | c.5374G>C p.E1792Q | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.321); catalogued as COSV62745401; called by muse, mutect2, varscan2
- NDC80 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as COSV55246865; called by muse, mutect2, varscan2
- NF1 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV62193050; called by muse, mutect2, varscan2
- NFATC1 | c.1604G>C p.G535A | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53695144; called by muse, mutect2, varscan2
- NFE2L1 | c.577del p.D193Tfs*37 | Frame Shift Del (DEL) | VAF 59/356 reads (17%) | catalogued as COSV62582790; called by mutect2, pindel, varscan2
- NFE2L3 | c.2008G>A p.G670R | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50226303; called by muse, mutect2, varscan2
- NFIB | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV66620317; called by muse, mutect2
- NLGN4Y | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.579); catalogued as COSV52969098; called by muse, mutect2
- NOS2 | c.1804G>A p.G602R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752529399, COSV58221775; called by muse, mutect2, varscan2
- ONECUT1 | c.724G>T p.V242L | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.071); catalogued as COSV59947847; called by muse, mutect2, varscan2
- OR13C2 | c.770T>C p.F257S | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs756594098, COSV73377638; called by muse, mutect2, varscan2
- OR5H15 | c.103T>G p.Y35D | Missense Mutation (SNP) | VAF 144/317 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62947357; called by muse, mutect2, varscan2
- OXTR | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV100373249, COSV57478392; called by muse, mutect2, varscan2
- PA2G4 | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57246843; called by muse, mutect2, varscan2
- PBRM1 | c.3784A>G p.N1262D (on ENST00000296302 / NM_001366071.2; = p.N1237D on NM_018313.5) | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.68); PolyPhen benign (0.079); catalogued as COSV56261199; called by muse, mutect2, varscan2
- PCDH10 | c.236T>C p.I79T | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52087571; called by muse, mutect2, varscan2
- PCDH9 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 86/204 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.932); catalogued as COSV60528866; called by muse, mutect2, varscan2
- PCDH9 | c.1970C>G p.S657C | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60528878; called by muse, mutect2, varscan2
- PCDHB7 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50754021, COSV50784549; called by muse, mutect2, varscan2
- PCNA | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV52531697; called by muse, mutect2, varscan2
- PDE12 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100239721, COSV60818144; called by muse, mutect2, varscan2
- PER1 | c.3766G>A p.G1256S | Missense Mutation (SNP) | VAF 64/235 reads (27%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); catalogued as COSV57917317; called by muse, mutect2, varscan2
- PEX1 | c.3683C>T p.A1228V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV50394599; called by muse, mutect2, varscan2
- PFN1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.478); catalogued as rs1263497093, COSV52590306; called by muse, mutect2, varscan2
- PGBD1 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV52551322, COSV52551801; called by muse, mutect2, varscan2
- PHLDA3 | c.187_195del p.C63_E65del | In Frame Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs777599476; called by mutect2, varscan2
- PIKFYVE | c.565A>T p.S189C | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52236978; called by muse, mutect2, varscan2
- PIP4K2C | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV61605687; called by muse, mutect2, varscan2
- PLPPR5 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV54169043; called by muse, mutect2, varscan2
- POLD3 | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55240989; called by muse, mutect2, varscan2
- PPP1R3B | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV60098912; called by muse, mutect2, varscan2
- PPP2R1B | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV59534649; called by muse, mutect2, varscan2
- PPP3CC | c.390G>T p.W130C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51499385; called by muse, mutect2, varscan2
- PRRC2B | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV61933743; called by muse, mutect2, varscan2
- PSMA5 | c.148G>C p.V50L | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV54748055; called by muse, mutect2, varscan2
- PTPRD | c.3748G>A p.V1250M | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as rs772029273, COSV100644112, COSV61928581; called by muse, mutect2, varscan2
- PTPRU | c.500C>G p.S167C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV60521782; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2657G>A p.G886E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV51478770; called by muse, mutect2, varscan2
- RAD9B | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV63777427; called by muse, mutect2, varscan2
- RAP1GAP | c.474+1G>T p.X158_splice | Splice Site (SNP) | VAF 32/70 reads (46%) | catalogued as COSV51568527; called by muse, mutect2, varscan2
- RBBP6 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 153/221 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs144821029; called by muse, mutect2, varscan2
- RC3H2 | c.3354G>C p.Q1118H | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.948); catalogued as COSV61798484; called by muse, mutect2, varscan2
- RECQL5 | c.2927G>T p.R976L | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV58637393, COSV58639469; called by muse, mutect2, varscan2
- REL | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV54362348; called by muse, mutect2, varscan2
- REV3L | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62614958; called by muse, mutect2, varscan2
- RGS16 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV62375476; called by muse, mutect2, varscan2
- RHBDL1 | c.317C>T p.P106L (on ENST00000219551 / NM_001318733.2; = p.P41L on NM_001278720.2) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767000541, COSV54802299, COSV99558189; called by muse, mutect2, varscan2
- RIMS2 | c.812C>G p.S271* (on ENST00000666250 / NM_001348490.2; = p.S79* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as COSV51686653; called by muse, mutect2, varscan2
- RIOK3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV59772023; called by muse, mutect2, varscan2
- RNF10 | c.856T>C p.Y286H | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs756519075, COSV58043486; called by muse, mutect2, varscan2
- RPTOR | c.3512G>A p.S1171N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.336); catalogued as COSV60803275; called by muse, mutect2, varscan2
- RRBP1 | c.3544G>A p.E1182K (on ENST00000377813 / NM_001365613.2; = p.E749K on NM_004587.3) | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV55695748; called by muse, mutect2, varscan2
- RRBP1 | c.3172C>G p.L1058V (on ENST00000377813 / NM_001365613.2; = p.L625V on NM_004587.3) | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.06); catalogued as COSV55695769; called by muse, mutect2, varscan2
- SAP130 | c.3038G>C p.R1013T | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV52094265; called by muse, mutect2, varscan2
- SELENON | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as rs757780272, COSV62523924; called by muse, mutect2, varscan2
- SEMA6D | c.2798C>T p.P933L (on ENST00000316364 / NM_153618.2; = p.P871L on NM_020858.2) | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV60372814; called by muse, mutect2, varscan2
- SH3GL1 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV54173323; called by muse, mutect2, varscan2
- SHKBP1 | c.652A>G p.R218G | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52537617; called by muse, mutect2, varscan2
- SHROOM3 | c.3821G>A p.G1274E | Missense Mutation (SNP) | VAF 67/129 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV56023244; called by muse, mutect2, varscan2
- SLC12A3 | c.896A>G p.N299S | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.402); catalogued as rs760801549, COSV52632514; called by muse, mutect2, varscan2
- SLC30A1 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65360500, COSV65361528; called by muse, mutect2, varscan2
- SLC38A2 | c.995T>G p.F332C | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56744025; called by muse, mutect2, varscan2
- SLC6A7 | c.1720C>T p.R574W | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs144483863; called by muse, mutect2, varscan2
- SLITRK1 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV65674235; called by muse, mutect2, varscan2
- SLK | c.3653A>G p.Q1218R | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV59823755; called by muse, mutect2, varscan2
- SMC4 | c.1717A>G p.K573E | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV61002967; called by muse, mutect2, varscan2
- SMOX | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs566360232, COSV53862988; called by muse, mutect2, varscan2
- SNCG | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.36); catalogued as rs1206267629, COSV62317988; called by muse, mutect2
- ST3GAL5 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV60384972; called by muse, mutect2, varscan2
- STK38 | c.284T>C p.I95T | Missense Mutation (SNP) | VAF 102/127 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57707503; called by muse, mutect2, varscan2
- SUSD2 | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV64202743; called by muse, mutect2, varscan2
- SVEP1 | c.6796A>G p.K2266E | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs373682897, COSV52835455; called by muse, mutect2, varscan2
- TAB3 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV55834348; called by muse, mutect2, varscan2
- TAPT1 | c.1663G>C p.E555Q | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV58822848; called by muse, mutect2, varscan2
- TARS2 | c.1617G>T p.K539N | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64694508; called by muse, mutect2, varscan2
- TAS1R3 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs757330832, COSV59562190; called by muse, mutect2, varscan2
- TBC1D14 | c.843G>A p.K281= | Splice Region (SNP) | VAF 24/85 reads (28%) | catalogued as COSV101298986, COSV68984477; called by muse, mutect2, varscan2
- TBC1D26 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV68608607; called by muse, mutect2, varscan2
- TEAD2 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV60872294; called by muse, mutect2, varscan2
- THRAP3 | c.1188A>C p.K396N | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV63566623; called by muse, mutect2, varscan2
- TM9SF3 | c.960-1G>A p.X320_splice | Splice Site (SNP) | VAF 34/77 reads (44%) | catalogued as COSV64456597; called by muse, mutect2, varscan2
- TM9SF3 | c.746G>A p.R249K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as COSV64456601; called by muse, mutect2, varscan2
- TMEM120B | c.878C>G p.S293C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV57362604; called by muse, mutect2, varscan2
- TMEM44 | c.381G>C p.K127N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV56447294; called by muse, mutect2, varscan2
- TOP2B | c.4732G>A p.D1578N (on ENST00000264331 / NM_001330700.2; = p.D1573N on NM_001068.3) | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.084); catalogued as COSV51968608, COSV51969917, COSV51971143; called by muse, mutect2
- TP53 | c.1146del p.K382Nfs*40 | Frame Shift Del (DEL) | VAF 50/131 reads (38%) | catalogued as CD126191; called by mutect2, pindel, varscan2
- TRA2B | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV52024687; called by muse, mutect2, varscan2
- TRIM14 | c.537+1G>A p.X179_splice | Splice Site (SNP) | VAF 29/51 reads (57%) | catalogued as COSV58353212; called by muse, mutect2, varscan2
- TRMT1 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as rs1263756312; called by muse, mutect2, varscan2
- TRMT1 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV55564591; called by muse, mutect2, varscan2
- TRMT1 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV52833919; called by muse, mutect2, varscan2
- TRPC6 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60250880; called by muse, mutect2
- TRRAP | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.039); catalogued as COSV62838897; called by muse, mutect2, varscan2
- TTL | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV51973237; called by muse, mutect2, varscan2
- UBE3B | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs1342392588, COSV55091168; called by muse, mutect2, varscan2
- UBE3C | c.1242G>T p.R414S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.283); catalogued as rs984153189; called by muse, mutect2
- UHRF1BP1 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51952715; called by muse, mutect2, varscan2
- UQCRB | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.139); catalogued as rs754329213, COSV54629113, COSV99749307; called by muse, mutect2, varscan2
- USP43 | c.1644C>G p.F548L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53299721; called by muse, mutect2, varscan2
- UTP20 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs772729936, COSV55372056; called by muse, mutect2, varscan2
- WDR70 | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV54266534; called by muse, mutect2, varscan2
- YTHDC1 | c.1868A>G p.Y623C (on ENST00000344157 / NM_001031732.4; = p.Y605C on NM_133370.4) | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60008649; called by muse, mutect2, varscan2
- YWHAQ | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV53002521; called by muse, mutect2, varscan2
- ZBTB49 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as rs776918894, COSV61924277; called by muse, mutect2, varscan2
- ZCWPW2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV67497535; called by muse, mutect2, varscan2
- ZIC2 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.811); catalogued as rs757262942; called by muse, mutect2, varscan2
- ZNF222 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs773950473, COSV51825791; called by muse, mutect2, varscan2
- ZNF276 | c.487G>A p.G163S (on ENST00000443381 / NM_001113525.2; = p.G88S on NM_152287.4) | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.68); catalogued as rs748405201, COSV57065622; called by muse, mutect2, varscan2
- ZNF615 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs867017213, COSV65032009; called by muse, mutect2, varscan2
- ZNF792 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 137/331 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV68692718; called by muse, mutect2, varscan2
- AFF4 | c.3403dup p.I1135Nfs*3 | Frame Shift Ins (INS) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- ANXA6 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ARHGEF18 | c.1190C>G p.S397* (on ENST00000359920 / NM_001130955.2; = p.S293* on NM_015318.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP6V1D | c.425_456del p.V142Dfs*8 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel
- CCDC144A | c.4241T>G p.L1414R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.432); called by mutect2, varscan2
- CCDC89 | c.153_161del p.N51_G54delinsK | In Frame Del (DEL) | VAF 29/74 reads (39%) | called by mutect2, pindel*, varscan2*
- CFAP54 | c.6898G>C p.E2300Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- CPSF6 | c.729_746del p.G248_P253del | In Frame Del (DEL) | VAF 13/84 reads (15%) | called by mutect2, pindel, varscan2
- CXXC1 | c.318_324del p.G107Afs*82 | Frame Shift Del (DEL) | VAF 40/99 reads (40%) | called by mutect2, pindel, varscan2
- DNAH3 | c.5439+1_5439+5del p.X1813_splice | Splice Site (DEL) | VAF 42/62 reads (68%) | called by mutect2, pindel, varscan2
- E2F8 | c.125_139del p.L42_K47delins* | Nonsense Mutation (DEL) | VAF 70/170 reads (41%) | called by mutect2, pindel, varscan2
- FANCC | c.968T>G p.V323G | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2
- GIMAP2 | c.762_763insCCACA p.A255Pfs*10 | Frame Shift Ins (INS) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- H6PD | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 39/69 reads (57%) | called by muse, mutect2, varscan2
- IL19 | c.311_313dup p.I104dup | In Frame Ins (INS) | VAF 53/142 reads (37%) | called by mutect2, pindel, varscan2
- INTS1 | c.4791dup p.K1598Efs*177 | Frame Shift Ins (INS) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- MEGF8 | c.3254G>A p.C1085Y (on ENST00000251268 / NM_001271938.2; = p.C1018Y on NM_001410.3) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO7B | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | called by mutect2, varscan2
- OTUD3 | c.809_835del p.L270_N279delinsH | In Frame Del (DEL) | VAF 15/95 reads (16%) | called by mutect2, pindel
- OTUD4 | c.1124C>G p.S375* (on ENST00000447906 / NM_001366057.1; = p.S310* on NM_001102653.1) | Nonsense Mutation (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- PCDHGC4 | c.589del p.E197Rfs*16 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- PHRF1 | c.3368G>A p.C1123Y (on ENST00000264555 / NM_001286581.2; = p.C1122Y on NM_020901.4) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- PLEC | c.11886G>C p.Q3962H (on ENST00000322810 / NM_201380.4; = p.Q3852H on NM_000445.5) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); called by muse, mutect2
- SEC61A2 | c.580A>T p.K194* | Nonsense Mutation (SNP) | VAF 45/142 reads (32%) | called by muse, mutect2, varscan2
- SERHL2 | c.423+2T>A p.X141_splice | Splice Site (SNP) | VAF 53/161 reads (33%) | called by muse, mutect2
- SLC27A5 | c.1614del p.M539Wfs*63 | Frame Shift Del (DEL) | VAF 29/78 reads (37%) | called by mutect2, pindel, varscan2
- SLC32A1 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- SOX10 | c.531del p.R178Gfs*108 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, pindel, varscan2
- SYNRG | c.1761A>T p.K587N | Missense Mutation (SNP) | VAF 84/117 reads (72%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- TIAM1 | c.3307G>T p.E1103* | Nonsense Mutation (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- TKFC | c.530T>A p.I177N | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TMEM181 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TMTC1 | c.939-1G>T p.X313_splice (on ENST00000539277 / NM_001193451.2; = p.X205_splice on NM_175861.3) | Splice Site (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2
- TP53 | c.350_366del p.G117Dfs*26 | Frame Shift Del (DEL) | VAF 15/83 reads (18%) | called by mutect2, pindel
- ZFYVE28 | c.2391_2399del p.E798_A800del | In Frame Del (DEL) | VAF 49/173 reads (28%) | called by mutect2, pindel, varscan2
- ACSS2 | c.876C>T p.L292= | Silent (SNP) | VAF 58/221 reads (26%) | catalogued as rs773777830, COSV53622560; called by muse, mutect2, varscan2
- ADNP | c.342C>T p.F114= | Silent (SNP) | VAF 46/166 reads (28%) | catalogued as COSV62424465; called by muse, mutect2, varscan2
- AP001781.2 | c.60G>A p.L20= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV52786279; called by muse, mutect2
- APBA2 | c.441G>A p.P147= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs375569614; called by muse, mutect2, varscan2
- APBA2 | c.2022C>T p.S674= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as rs766411423, COSV68788636; called by muse, mutect2, varscan2
- ASS1 | c.1062C>G p.L354= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs763822587, COSV61688467; called by muse, mutect2, varscan2
- ATG16L1 | c.1365T>C p.I455= (on ENST00000392017 / NM_030803.7; = p.I436= on NM_017974.4) | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as rs1407435493, COSV61464237; called by muse, mutect2, varscan2
- ATP2B2 | c.1920C>T p.R640= (on ENST00000352432; = p.R606= on NM_001683.5) | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs757329620, COSV59489132; called by muse, mutect2, varscan2
- B4GALNT3 | c.90C>A p.A30= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV56749691; called by muse, mutect2, varscan2
- BACH2 | c.1293G>A p.V431= | Silent (SNP) | VAF 61/77 reads (79%) | catalogued as COSV57584395; called by muse, mutect2, varscan2
- BANK1 | c.1335G>A p.Q445= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV59838343; called by muse, mutect2, varscan2
- BPI | c.285C>T p.P95= (on ENST00000262865; = p.P91= on NM_001725.3) | Silent (SNP) | VAF 53/164 reads (32%) | catalogued as COSV53403879; called by muse, mutect2, varscan2
- BRF1 | c.1401C>G p.A467= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as COSV59265917; called by muse, mutect2, varscan2
- C15orf39 | c.21G>A p.L7= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs914974262, COSV62295717; called by muse, mutect2, varscan2
- CDC42BPB | c.570C>T p.S190= | Silent (SNP) | VAF 60/149 reads (40%) | catalogued as COSV63473872; called by muse, mutect2, varscan2
- CLEC16A | c.132G>A p.R44= | Silent (SNP) | VAF 41/67 reads (61%) | catalogued as rs771009990, COSV68497885; called by muse, mutect2, varscan2
- CNGA2 | c.1821C>T p.N607= | Silent (SNP) | VAF 89/122 reads (73%) | catalogued as COSV100323973, COSV61703190; called by muse, mutect2, varscan2
- CNTN1 | c.1446T>C p.Y482= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV61636178; called by muse, mutect2, varscan2
- COL5A1 | c.4470C>A p.L1490= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV65665002, COSV65665926; called by muse, mutect2, varscan2
- CPAMD8 | c.285C>T p.V95= (on ENST00000651564; = p.V48= on NM_015692.5) | Silent (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- CTSO | c.753A>G p.Q251= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV70808816; called by muse, mutect2, varscan2
- DALRD3 | c.1161G>C p.L387= (on ENST00000341949 / NM_001009996.3; = p.L220= on NM_018114.5) | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- DEF8 | c.42G>A p.A14= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs1318074496, COSV51917755; called by muse, mutect2, varscan2
- DENND5A | c.2868C>T p.Y956= | Silent (SNP) | VAF 190/437 reads (43%) | catalogued as COSV60231390; called by muse, mutect2, varscan2
- DIP2A | c.1464G>A p.G488= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV59471876; called by muse, mutect2, varscan2
- DMKN | c.1143C>T p.V381= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV60084437; called by muse, mutect2, varscan2
- DNAJB13 | c.888C>T p.I296= | Silent (SNP) | VAF 28/182 reads (15%) | catalogued as COSV60104278; called by muse, mutect2, varscan2
- DNAJB5 | c.849C>A p.I283= | Silent (SNP) | VAF 46/264 reads (17%) | catalogued as COSV56624636; called by muse, mutect2, varscan2
- DNAJC13 | c.432C>G p.T144= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs1204309541, COSV53445651; called by muse, mutect2, varscan2
- DPEP3 | c.1440C>T p.I480= | Silent (SNP) | VAF 13/17 reads (76%) | catalogued as COSV52050338; called by muse, mutect2, varscan2
- DPH2 | c.66G>A p.L22= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as COSV52542512; called by muse, mutect2, varscan2
- EBF1 | c.807G>A p.P269= | Silent (SNP) | VAF 31/38 reads (82%) | catalogued as rs781723383, COSV58166509, COSV58167438; called by muse, mutect2, varscan2
- EEF2 | c.795C>T p.Y265= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as rs532385897, COSV58578572; called by muse, mutect2, varscan2
- EIF2AK4 | c.1824G>A p.Q608= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV55464950; called by muse, mutect2, varscan2
- F12 | c.855G>A p.L285= | Silent (SNP) | VAF 19/23 reads (83%) | catalogued as COSV53690021; called by muse, mutect2, varscan2
- FAM83F | c.762G>A p.V254= | Silent (SNP) | VAF 44/67 reads (66%) | catalogued as COSV60999423; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.747C>T p.L249= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as COSV58545782; called by muse, mutect2, varscan2
- FZD2 | c.84G>A p.E28= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV59528091; called by muse, mutect2
- GJB4 | c.702C>T p.C234= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV58355456; called by muse, mutect2, varscan2
- GPR155 | c.2289C>T p.I763= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV55037300; called by muse, mutect2, varscan2
- GSTM4 | c.141G>A p.L47= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV58693816; called by muse, mutect2, varscan2
- HBA1 | c.411G>A p.L137= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- HLCS | c.1455G>A p.L485= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV100358113, COSV60791353; called by muse, varscan2
- HOXB1 | c.618C>T p.L206= | Silent (SNP) | VAF 41/164 reads (25%) | catalogued as COSV53316340; called by muse, mutect2, varscan2
- HSPA2 | c.1329G>A p.V443= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as rs1190304333, COSV55968728; called by muse, mutect2, varscan2
- HTR1F | c.258A>G p.R86= | Silent (SNP) | VAF 5/89 reads (6%) | catalogued as COSV60388977; called by muse, mutect2
- HTR6 | c.255G>A p.L85= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV57032018; called by muse, mutect2, varscan2
- INO80 | c.3033T>C p.C1011= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV62736108; called by muse, mutect2, varscan2
- IRAK1BP1 | c.228C>T p.S76= | Silent (SNP) | VAF 20/25 reads (80%) | catalogued as rs1428844502, COSV64047876; called by muse, mutect2, varscan2
- ITPR3 | c.2085G>T p.T695= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV65405674; called by muse, mutect2, varscan2
- KDM4C | c.807C>T p.F269= | Silent (SNP) | VAF 50/109 reads (46%) | catalogued as rs756307522, COSV67183635; called by muse, mutect2, varscan2
- KLB | c.1893G>A p.L631= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs1220812968, COSV57300076; called by muse, mutect2, varscan2
- LIMA1 | c.1473A>T p.P491= | Silent (SNP) | VAF 35/144 reads (24%) | catalogued as COSV57963885; called by muse, mutect2, varscan2
- LIMS2 | c.637C>T p.L213= (on ENST00000355119 / NM_001161403.3; = p.L237= on NM_017980.4) | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- LPAR6 | c.990A>G p.L330= | Silent (SNP) | VAF 65/89 reads (73%) | catalogued as rs1328958817, COSV57296238; called by muse, mutect2, varscan2
- LRRC8A | c.1422G>A p.L474= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV52184061; called by mutect2, varscan2
- LSM14B | c.900C>T p.P300= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs370488847; called by muse, mutect2, varscan2
- MPDU1 | c.351C>T p.C117= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as rs939071585, COSV51467452; called by muse, mutect2, varscan2
- MPND | c.1254C>T p.F418= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as COSV53655854; called by muse, mutect2, varscan2
- N4BP2 | c.3486T>C p.I1162= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV54698938; called by muse, mutect2, varscan2
- NCAPD2 | c.3336G>A p.A1112= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as rs149244253; called by muse, mutect2, varscan2
- NCOA7 | c.2142C>G p.V714= | Silent (SNP) | VAF 85/115 reads (74%) | catalogued as COSV57652339; called by muse, mutect2, varscan2
- NLRP1 | c.2583G>A p.L861= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV52558489; called by muse, mutect2, varscan2
- NSF | c.1572G>A p.L524= | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as COSV56573802; called by muse, mutect2, varscan2
- NSMCE1 | c.216G>A p.K72= | Silent (SNP) | VAF 35/51 reads (69%) | catalogued as COSV63863793, COSV63864835; called by muse, mutect2, varscan2
- NTN4 | c.1308G>A p.V436= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV59217158; called by muse, mutect2, varscan2
- OBSL1 | c.987C>T p.L329= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV54712764; called by muse, mutect2
- OR8J1 | c.135C>T p.I45= | Silent (SNP) | VAF 59/147 reads (40%) | catalogued as COSV57316534; called by muse, mutect2, varscan2
- OR9Q1 | c.300G>A p.Q100= | Silent (SNP) | VAF 54/136 reads (40%) | catalogued as COSV59036730; called by muse, mutect2, varscan2
- P2RY10 | c.639C>T p.I213= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs1270835675, COSV50680353; called by muse, mutect2, varscan2
- P4HA2 | c.1497A>T p.T499= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV51323788; called by muse, mutect2, varscan2
- PAPPA2 | c.2151C>T p.L717= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV62772913; called by muse, mutect2, varscan2
- PITX3 | c.504G>A p.K168= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV64174121; called by muse, mutect2, varscan2
- PLEKHG3 | c.528C>G p.L176= (on ENST00000394691; = p.L232= on NM_001308147.2) | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV55977663; called by muse, mutect2, varscan2
- POF1B | c.1323T>C p.S441= | Silent (SNP) | VAF 43/56 reads (77%) | catalogued as COSV53130324; called by muse, mutect2, varscan2
- PROC | c.852G>A p.E284= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as rs780286813, COSV52164690; called by muse, mutect2, varscan2
- PRPF3 | c.768G>T p.L256= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV61393859; called by muse, mutect2, varscan2
- PTPN13 | c.2751C>T p.L917= | Silent (SNP) | VAF 31/126 reads (25%) | catalogued as COSV57402720; called by muse, mutect2, varscan2
- PTPN6 | c.729C>T p.G243= | Silent (SNP) | VAF 19/133 reads (14%) | catalogued as rs782721984, COSV59683343; called by muse, mutect2, varscan2
- RAB43 | c.483G>C p.T161= | Silent (SNP) | VAF 5/18 reads (28%) | called by muse, varscan2
- RANBP6 | c.807G>A p.L269= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV52388132; called by muse, mutect2, varscan2
- RBBP4 | c.717T>C p.H239= | Silent (SNP) | VAF 55/133 reads (41%) | catalogued as rs1424865403, COSV65132005; called by muse, mutect2, varscan2
- RSPH1 | c.25T>C p.L9= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV52318330; called by muse, mutect2, varscan2
- RUFY2 | c.1902G>A p.Q634= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as COSV56258562; called by muse, mutect2, varscan2
- SARDH | c.138G>A p.L46= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV53831903; called by muse, mutect2, varscan2
- SCCPDH | c.1071T>C p.N357= | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as COSV63618074; called by muse, mutect2, varscan2
- SCN8A | c.1803C>G p.L601= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV61976506; called by muse, mutect2, varscan2
- SCTR | c.588C>T p.D196= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs746911205, COSV50026827; called by muse, mutect2, varscan2
- SDC1 | c.135C>A p.S45= | Silent (SNP) | VAF 64/97 reads (66%) | catalogued as COSV54338757; called by muse, mutect2, varscan2
- SEC24D | c.1401C>A p.T467= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as COSV54876747; called by muse, mutect2, varscan2
- SECISBP2 | c.1656G>A p.V552= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs1478740144; called by muse, mutect2
- SEMA5A | c.1848G>A p.Q616= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV66784708; called by muse, mutect2, varscan2
- SLC16A7 | c.591C>G p.P197= | Silent (SNP) | VAF 31/49 reads (63%) | catalogued as COSV53892145; called by muse, mutect2, varscan2
- SPEN | c.10959C>T p.I3653= | Silent (SNP) | VAF 61/209 reads (29%) | catalogued as rs1428239536, COSV65268155; called by muse, mutect2, varscan2
- SPOCD1 | c.2880T>A p.S960= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV57093747; called by muse, mutect2, varscan2
- SREK1 | c.1503C>G p.L501= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs1260935755, COSV52331725, COSV52331998; called by muse, mutect2, varscan2
- STKLD1 | c.312C>T p.L104= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV100911840, COSV64311686; called by muse, mutect2, varscan2
- STN1 | c.729G>A p.V243= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs757861791, COSV56544063; called by muse, mutect2, varscan2
- SYPL1 | c.72C>T p.I24= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV50578686; called by muse, mutect2, varscan2
- TACC2 | c.4932T>C p.P1644= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV57746200; called by muse, mutect2, varscan2
- TACC3 | c.1824A>G p.A608= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV57602780; called by muse, mutect2, varscan2
- TAF6L | c.1074C>T p.V358= | Silent (SNP) | VAF 28/156 reads (18%) | catalogued as COSV53667279; called by muse, mutect2, varscan2
- TAPT1 | c.1200G>C p.R400= | Silent (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- TAS1R3 | c.1014G>A p.V338= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV59562181; called by muse, mutect2, varscan2
- TBC1D13 | c.954C>T p.F318= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV56353419; called by muse, varscan2
- TBC1D13 | c.1023C>G p.L341= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV56353426; called by muse, varscan2
- TBC1D22B | c.1038C>T p.S346= | Silent (SNP) | VAF 109/132 reads (83%) | catalogued as COSV65142222; called by muse, mutect2, varscan2
- TMC6 | c.27C>T p.L9= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs145198906, COSV100130217; called by muse, mutect2, varscan2
- TMEM61 | c.252C>A p.G84= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as COSV64873350; called by muse, mutect2, varscan2
- TNR | c.2421C>T p.N807= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV54870493, COSV54873284, COSV99686713; called by muse, mutect2, varscan2
- TPH1 | c.759T>G p.T253= | Silent (SNP) | VAF 45/98 reads (46%) | catalogued as COSV51456703, COSV51458443; called by muse, mutect2, varscan2
- TRIM2 | c.1152C>T p.N384= (on ENST00000437508; = p.N411= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV58631029; called by muse, mutect2, varscan2
- TRIM38 | c.357A>G p.P119= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as COSV62641669; called by muse, mutect2, varscan2
- TTN | c.21450T>C p.T7150= (on ENST00000591111; = p.T6223= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/60 reads (58%) | catalogued as COSV59887979; called by muse, mutect2
- UBR4 | c.11637C>T p.V3879= | Silent (SNP) | VAF 47/164 reads (29%) | catalogued as COSV64382840; called by muse, mutect2, varscan2
- UGT1A10 | c.315A>C p.I105= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV60831409; called by muse, mutect2, varscan2
- UNC79 | c.7260G>A p.L2420= (on ENST00000393151 / NM_001346218.2; = p.L2243= on NM_020818.5) | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as rs1249334581, COSV56373907; called by muse, mutect2, varscan2
- VCX | c.351G>A p.E117= | Silent (SNP) | VAF 112/205 reads (55%) | catalogued as COSV58231883; called by muse, varscan2
- VPS13D | c.8718C>T p.T2906= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV50621752; called by muse, mutect2, varscan2
- VSTM2A | c.387G>T p.V129= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV56492224; called by muse, mutect2, varscan2
- VWA3B | c.1017C>T p.L339= | Silent (SNP) | VAF 28/45 reads (62%) | catalogued as rs1191455728, COSV68240917; called by muse, mutect2, varscan2
- XRCC3 | c.924C>T p.L308= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs759227523, COSV57976896; called by muse, mutect2, varscan2
- YIPF2 | c.264C>T p.D88= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs374465630, COSV53402728; called by muse, mutect2, varscan2
- ZMIZ1 | c.465G>A p.Q155= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV57889681; called by muse, mutect2, varscan2
- ZNF423 | c.669C>T p.T223= (on ENST00000563137 / NM_001379286.1; = p.T215= on NM_015069.4) | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as rs775209030, COSV52177325, COSV52183383; called by muse, mutect2, varscan2
- ZNF84 | c.1719C>T p.C573= | Silent (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- ACOT11 | c.1629+935C>T | Intron (SNP) | VAF 37/159 reads (23%) | catalogued as COSV56362973; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65497969 del CCAGGTGGTGGTATTTAGATAAAA | 5'Flank (DEL) | VAF 29/130 reads (22%) | called by mutect2, pindel, varscan2
- C12orf77 | n.287C>G | RNA (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- COLEC12 | c.*2G>A | 3'UTR (SNP) | VAF 13/61 reads (21%) | catalogued as rs879124076, COSV101232006, COSV101232015; called by muse, mutect2, varscan2
- DCHS2 | n.8093G>C | RNA (SNP) | VAF 23/64 reads (36%) | catalogued as COSV61768031; called by muse, mutect2, varscan2
- ECPAS | chr9:111484533 G>T | 5'Flank (SNP) | VAF 8/32 reads (25%) | catalogued as COSV52191582; called by mutect2, varscan2
- EPDR1 | c.-189_-175delinsA | 5'UTR (DEL) | VAF 19/39 reads (49%) | called by pindel, varscan2*
- FBXL18 | c.2000+1062T>A | Intron (SNP) | VAF 17/43 reads (40%) | catalogued as rs1461501611, COSV66665166; called by muse, mutect2, varscan2
- LINC01559 | n.585G>C | RNA (SNP) | VAF 34/138 reads (25%) | catalogued as rs778675192; called by muse, mutect2, varscan2
- MYADM | chr19:53874367 A>C | 3'Flank (SNP) | VAF 16/73 reads (22%) | catalogued as COSV61238563; called by muse, mutect2, varscan2
- PLCE1 | c.1207-43015A>G | Intron (SNP) | VAF 26/84 reads (31%) | catalogued as COSV53336736; called by muse, mutect2, varscan2
- VPS26C | chr21:37221262 T>C | 3'Flank (SNP) | VAF 33/62 reads (53%) | catalogued as rs376026635; called by muse, mutect2, varscan2
